Somatic mutation profile of tumor specimen TCGA-AB-2875-03A (aliquot TCGA-AB-2875-03A-01W-0732-08) from TCGA case TCGA-AB-2875, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.8 years (16,010 days).
Specimen TCGA-AB-2875-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64dc80b4-5f84-40ba-98eb-20aafbcf7798.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2875-11A (Solid Tissue Normal), aliquot TCGA-AB-2875-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc5d728-015c-4242-a043-4f6b7c832996

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB10 | c.715dup p.A239Gfs*4 (on ENST00000420175 / NM_001142459.2; = p.A224Gfs*4 on NM_080871.4) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs750715799; called by mutect2, pindel
- BMPER | c.49C>A p.R17S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as rs753940001, COSV51832700; called by muse, mutect2, varscan2
- CADM3 | c.485G>A p.R162Q (on ENST00000368125 / NM_001127173.3; = p.R196Q on NM_021189.5) | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs148250608; called by muse, mutect2, varscan2
- CEP290 | c.3953C>T p.T1318I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1417537739, COSV58356958; called by muse, mutect2, varscan2
- DGKA | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 26/1076 reads (2%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59384530; called by muse, mutect2
- DRD2 | c.1140C>T p.G380= | Splice Region (SNP) | VAF 56/140 reads (40%) | catalogued as rs201123323, COSV60759040; called by muse, mutect2, varscan2
- MAP2 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.671); catalogued as rs758152120, COSV52309741; called by muse, mutect2, varscan2
- MTOR | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.974); catalogued as rs762176419, COSV63871869; called by muse, mutect2, varscan2
- MYLK | c.2038C>A p.L680I | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60623895; called by muse, mutect2, varscan2
- TRPM2 | c.3274C>A p.L1092I | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV55969740; called by muse, mutect2
- FCGBP | c.834C>T p.Y278= | Silent (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
